Somatic mutation profile of cancer-model specimen HCM-BROD-0755-C43-85M (Adherent Cell Line, passage 8; aliquot HCM-BROD-0755-C43-85M-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0755-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lentigo maligna melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.5 years (22,812 days).
Specimen HCM-BROD-0755-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c473439-74c7-4070-a91f-764ebfd88c34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0755-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0755-C43-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f11f3077-cb00-43c1-b0c4-eb1b222d30d7

The open-access MAF lists 225 somatic variants for this specimen: 146 protein-altering or splice-affecting, 71 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 71, Nonsense Mutation 6, Intron 4, Frame Shift Del 3, Splice Region 3, 3'UTR 2, RNA 1, Splice Site 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 235/436 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 166/166 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 305/305 reads (100%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ABCD1 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 56/1104 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs76180859, COSV54383694; ClinVar: benign; called by muse, mutect2
- ACAN | c.6589G>A p.E2197K | Missense Mutation (SNP) | VAF 152/694 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs751604379, COSV100718660; called by muse, varscan2
- ACSM4 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 117/252 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV68066569; called by muse, mutect2, varscan2
- ACTN2 | c.1325G>C p.R442P | Missense Mutation (SNP) | VAF 390/632 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63974666; called by muse, mutect2, varscan2
- ADAM7 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs867202281, COSV51534566; called by muse, mutect2, varscan2
- ADGRB1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 144/498 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1422973787, COSV60102534; called by muse, varscan2
- ALG1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 125/415 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1351552189; called by muse, mutect2, varscan2
- CAPRIN1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 176/553 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.831); catalogued as rs770391108; called by muse, varscan2
- CBLN1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 57/678 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.755); catalogued as COSV54654945; called by muse, mutect2
- CCNB3 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 526/909 reads (58%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs782570615; called by muse, varscan2
- CLVS1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 121/546 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV57970800; called by muse, mutect2, varscan2
- COL5A1 | c.914A>C p.E305A | Missense Mutation (SNP) | VAF 130/415 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65673636; called by muse, mutect2, varscan2
- COL8A1 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 545/545 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99658689; called by muse, mutect2, varscan2
- CYP2C18 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 138/138 reads (100%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV53669788, COSV99608889; called by muse, mutect2, varscan2
- DNAI2 | c.-11-8C>T | Splice Region (SNP) | VAF 543/545 reads (100%) | catalogued as rs746614043; called by muse, mutect2, varscan2
- DSG1 | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 268/405 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57136234; called by muse, mutect2, varscan2
- EML3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 289/450 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53882939, COSV53883848; called by muse, varscan2
- FAM13A | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 141/434 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs770942446; called by muse, mutect2, varscan2
- FLNB | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 265/265 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99914013; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 211/301 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100435432; called by muse, mutect2, varscan2
- FSCN3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 515/892 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs142804912; called by muse, varscan2
- GLYATL3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 84/377 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs892646871; called by muse, mutect2, varscan2
- GNAS | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 562/1363 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV58341829; called by muse, mutect2, varscan2
- GPS2 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 288/289 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100222689; called by muse, mutect2, varscan2
- IL3RA | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 391/1023 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as rs780337362; called by muse, mutect2, varscan2
- KCNH7 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 125/283 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100147340; called by muse, varscan2
- KCNK10 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 217/474 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1388738317, COSV100068090; called by muse, mutect2, varscan2
- KRT38 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 492/493 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs371116367; called by muse, mutect2, varscan2
- KRT81 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 174/469 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1283138820; called by muse, varscan2
- KRTAP10-4 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 387/659 reads (59%) | catalogued as rs1555923437; called by muse, varscan2
- KRTAP29-1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 696/698 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1241455186; called by muse, varscan2
- LMBRD2 | c.1302+1G>A p.X434_splice | Splice Site (SNP) | VAF 91/91 reads (100%) | catalogued as rs779535050; called by muse, varscan2
- LOXHD1 | c.4825G>A p.D1609N | Missense Mutation (SNP) | VAF 368/534 reads (69%) | SIFT tolerated (0.51); PolyPhen benign (0.163); catalogued as rs1275751728, COSV56063616; called by muse, mutect2, varscan2
- LRRC30 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 176/546 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs1359908134; called by muse, mutect2, varscan2
- ME1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV63838998; called by muse, mutect2, varscan2
- MGAM | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 153/875 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV72075840; called by muse, mutect2, varscan2
- MXRA5 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 407/958 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV54224676; called by muse, mutect2, varscan2
- MYO18A | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 111/329 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773019180; called by muse, varscan2
- NEXMIF | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 496/865 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747436946, COSV50021850; called by muse, mutect2, varscan2
- OPLAH | c.3312G>A p.M1104I | Missense Mutation (SNP) | VAF 172/674 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1554757875; called by muse, mutect2, varscan2
- OR4M1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 177/375 reads (47%) | catalogued as rs550760273, COSV60061725; called by muse, mutect2, varscan2
- OR51F2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 150/444 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760483116, COSV59065739; called by muse, varscan2
- PDE7B | c.951C>T p.I317= | Splice Region (SNP) | VAF 143/143 reads (100%) | catalogued as rs143991171, COSV57511661; called by muse, varscan2
- PLA2G7 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 201/474 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV99221682; called by muse, mutect2
- SDK1 | c.6500C>T p.P2167L | Missense Mutation (SNP) | VAF 270/1290 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs752023069; called by muse, mutect2, varscan2
- SLC17A1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 137/289 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781043595, COSV55078487; called by muse, mutect2, varscan2
- SYN3 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 353/531 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs147065250; called by muse, mutect2, varscan2
- SYT1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs773015890; called by muse, mutect2, varscan2
- TAC3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs758046530, COSV55648577; called by muse, mutect2, varscan2
- TSHZ1 | c.472C>T p.P158S (on ENST00000580243 / NM_001308210.2; = p.P113S on NM_005786.6) | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs934396009; called by mutect2, varscan2
- TTN | c.19723G>A p.E6575K (on ENST00000591111; = p.E5648K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 315/718 reads (44%) | PolyPhen possibly damaging (0.737); catalogued as rs185833299; called by muse, mutect2, varscan2
- UMODL1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 243/357 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as COSV68558172; called by muse, mutect2, varscan2
- UNC13C | c.6170G>A p.G2057E | Missense Mutation (SNP) | VAF 192/447 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs752792341, COSV52865133, COSV99512997; called by muse, mutect2, varscan2
- USP17L2 | c.1133G>A p.W378* | Nonsense Mutation (SNP) | VAF 533/743 reads (72%) | catalogued as rs1174186143; called by muse, varscan2
- USP22 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 372/372 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs778712056; called by muse, mutect2, varscan2
- UTP14A | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 122/706 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64086229; called by muse, varscan2
- ZFHX4 | c.7852G>A p.E2618K | Missense Mutation (SNP) | VAF 348/474 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV50510382; called by muse, mutect2, varscan2
- ZNF182 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 373/611 reads (61%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV59357632; called by muse, mutect2, varscan2
- ADGRF3 | c.2467G>C p.D823H (on ENST00000311519 / NM_001145168.1; = p.D624H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/732 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- ALOX12B | c.1091C>A p.P364Q | Missense Mutation (SNP) | VAF 398/398 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- ANKRD50 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 260/412 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, varscan2
- AOC1 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 572/1009 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARG1 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 89/165 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ARSH | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 169/847 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATG16L1 | c.476A>C p.N159T | Missense Mutation (SNP) | VAF 238/555 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2A2 | c.488del p.I163Kfs*3 | Frame Shift Del (DEL) | VAF 75/179 reads (42%) | called by mutect2, pindel, varscan2
- C2orf42 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 87/493 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CALB2 | c.627G>A p.K209= | Splice Region (SNP) | VAF 86/286 reads (30%) | called by muse, mutect2, varscan2
- CALN1 | c.611G>A p.S204N (on ENST00000329008 / NM_001017440.3; = p.S246N on NM_031468.4) | Missense Mutation (SNP) | VAF 100/586 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CAMTA1 | c.4288C>T p.P1430S | Missense Mutation (SNP) | VAF 116/476 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, varscan2
- CD36 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, varscan2
- CEMIP | c.1013A>T p.K338I | Missense Mutation (SNP) | VAF 304/450 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, varscan2
- COL22A1 | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 121/475 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A4 | c.3845G>A p.G1282E | Missense Mutation (SNP) | VAF 291/591 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, varscan2
- CUL5 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 93/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK3 | c.5734G>A p.D1912N | Missense Mutation (SNP) | VAF 620/621 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EFCC1 | c.1287T>G p.C429W | Missense Mutation (SNP) | VAF 195/289 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EPS15L1 | c.2594A>T p.N865I | Missense Mutation (SNP) | VAF 282/434 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FAM81B | c.44del p.R15Kfs*25 | Frame Shift Del (DEL) | VAF 11/132 reads (8%) | called by mutect2*, pindel, varscan2*
- FBXO40 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 174/524 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, varscan2
- FCRL2 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 196/296 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); called by muse, varscan2
- FHAD1 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 130/467 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GYPA | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 101/219 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HDAC4 | c.2272A>T p.S758C | Missense Mutation (SNP) | VAF 261/573 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HEATR1 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 194/306 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRNR | c.5335A>G p.S1779G | Missense Mutation (SNP) | VAF 77/848 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- HYDIN | c.10550C>A p.P3517H | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- INTU | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 255/372 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KATNIP | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 341/555 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLC3 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 390/618 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KPNA7 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 320/540 reads (59%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.876); called by muse, varscan2
- KRT28 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 232/233 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- LGR6 | c.2120C>T p.S707L (on ENST00000367278 / NM_001017403.1; = p.S655L on NM_021636.3) | Missense Mutation (SNP) | VAF 212/665 reads (32%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- LRRC37B | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 144/517 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRN1 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 470/470 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.159); called by muse, varscan2
- MAGEL2 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 278/1181 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); called by muse, varscan2
- MICALL2 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 427/1211 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRK | c.2842C>T p.H948Y | Missense Mutation (SNP) | VAF 113/574 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4D9 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 211/344 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- OTUB2 | c.65A>C p.H22P | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, varscan2
- PAK6 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 181/783 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- PCDH17 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 503/755 reads (67%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PER3 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 257/404 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PEX5L | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PKHD1L1 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 155/204 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PRAMEF11 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 68/598 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, varscan2
- PRMT9 | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, varscan2
- PRSS57 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 332/526 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, varscan2
- PSMC2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 264/453 reads (58%) | called by muse, mutect2, varscan2
- PTGDR | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 228/469 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RFX2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 407/685 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RPS24 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, varscan2
- RYR3 | c.14165G>A p.G4722E (on ENST00000389232; = p.G4723E on NM_001036.6) | Missense Mutation (SNP) | VAF 399/538 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH2D4B | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC1 | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 348/863 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SKI | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 314/478 reads (66%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, varscan2
- SLC10A2 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 129/366 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC13A1 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 321/582 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLC16A1 | c.1100T>C p.F367S | Missense Mutation (SNP) | VAF 139/436 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A4 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 518/519 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC7A3 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 365/652 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SMARCAD1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 150/464 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, varscan2
- SMOC1 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPESP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 111/408 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- TBC1D30 | c.1216G>A p.D406N (on ENST00000542120; = p.D243N on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/230 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRAV40 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 155/293 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPV4 | c.968_969del p.T323Sfs*10 | Frame Shift Del (DEL) | VAF 194/510 reads (38%) | called by pindel, varscan2
- TTLL4 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 166/707 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.28); called by muse, varscan2
- TTN | c.81880G>A p.E27294K (on ENST00000591111; = p.E19870K on NM_003319.4) | Missense Mutation (SNP) | VAF 102/235 reads (43%) | PolyPhen benign (0.157); called by muse, varscan2
- TUB | c.133C>T p.P45S (on ENST00000299506 / NM_177972.3; = p.P100S on NM_003320.4) | Missense Mutation (SNP) | VAF 246/690 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, varscan2
- TXNDC2 | c.421G>A p.A141T (on ENST00000306084 / NM_001098529.2; = p.A74T on NM_032243.6) | Missense Mutation (SNP) | VAF 241/695 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- USP26 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 159/842 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- WDFY4 | c.874T>A p.L292M | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); called by muse, varscan2
- WDR87 | c.6562G>A p.E2188K | Missense Mutation (SNP) | VAF 144/487 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- WNK3 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 409/750 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB10 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 204/974 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, varscan2
- ZC3H7A | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMYM4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZNF367 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 247/853 reads (29%) | called by muse, varscan2
- ZNF407 | c.5081C>T p.A1694V | Missense Mutation (SNP) | VAF 360/547 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF711 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by mutect2, varscan2
- ZNF99 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 243/396 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZP4 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACER1 | c.651C>T p.F217= | Silent (SNP) | VAF 106/380 reads (28%) | called by muse, mutect2, varscan2
- ACTL8 | c.1005T>C p.F335= | Silent (SNP) | VAF 159/452 reads (35%) | called by muse, mutect2, varscan2
- AFF3 | c.1098G>A p.L366= | Silent (SNP) | VAF 185/419 reads (44%) | catalogued as rs1345082853; called by muse, mutect2, varscan2
- ARHGAP6 | c.249C>T p.S83= | Silent (SNP) | VAF 756/1335 reads (57%) | called by muse, varscan2
- ARRDC2 | c.66C>T p.P22= | Silent (SNP) | VAF 240/763 reads (31%) | catalogued as rs773020251; called by muse, varscan2
- ARSH | c.186C>T p.F62= | Silent (SNP) | VAF 432/756 reads (57%) | catalogued as COSV66963605; called by muse, mutect2, varscan2
- ASTN1 | c.483C>T p.I161= | Silent (SNP) | VAF 85/288 reads (30%) | catalogued as COSV56067627; called by muse, varscan2
- BCOR | c.5121C>T p.F1707= (on ENST00000378444 / NM_001123385.2; = p.F1673= on NM_017745.6) | Silent (SNP) | VAF 590/1029 reads (57%) | catalogued as COSV100653479, COSV60715032; called by muse, mutect2, varscan2
- C2orf16 | c.3168G>A p.L1056= | Silent (SNP) | VAF 166/376 reads (44%) | called by muse, varscan2
- CACNA2D4 | c.879G>A p.V293= | Silent (SNP) | VAF 164/313 reads (52%) | catalogued as COSV54952808; called by muse, mutect2, varscan2
- CDH13 | c.1332G>A p.V444= | Silent (SNP) | VAF 141/532 reads (27%) | catalogued as rs1456699597, COSV99225587; called by muse, mutect2, varscan2
- CDH13 | c.1839G>A p.P613= | Silent (SNP) | VAF 237/355 reads (67%) | catalogued as rs753046992; called by muse, mutect2, varscan2
- CHRNA7 | c.789C>T p.S263= | Silent (SNP) | VAF 82/556 reads (15%) | called by muse, varscan2
- CMC1 | c.57C>T p.I19= | Silent (SNP) | VAF 224/224 reads (100%) | catalogued as rs779025944, COSV58364551; called by muse, mutect2, varscan2
- COL20A1 | c.2832C>T p.F944= | Silent (SNP) | VAF 98/518 reads (19%) | called by muse, mutect2, varscan2
- COL6A3 | c.4953G>A p.R1651= | Silent (SNP) | VAF 219/457 reads (48%) | called by muse, mutect2, varscan2
- CPAMD8 | c.3000C>T p.I1000= (on ENST00000651564; = p.I953= on NM_015692.5) | Silent (SNP) | VAF 203/343 reads (59%) | catalogued as rs375563538, COSV71596518; called by muse, varscan2
- CYP11B2 | c.498G>A p.R166= | Silent (SNP) | VAF 240/1100 reads (22%) | catalogued as COSV100011030; called by muse, mutect2
- DCAF8L2 | c.756G>A p.V252= | Silent (SNP) | VAF 592/1024 reads (58%) | called by muse, varscan2
- DNMT3L | c.396G>A p.G132= | Silent (SNP) | VAF 423/658 reads (64%) | catalogued as rs768443281; called by muse, mutect2, varscan2
- DONSON | c.630C>T p.L210= | Silent (SNP) | VAF 91/340 reads (27%) | catalogued as COSV99280997; called by muse, varscan2
- DYNLRB1 | c.99C>G p.T33= | Silent (SNP) | VAF 441/786 reads (56%) | called by muse, mutect2, varscan2
- EHMT2 | c.1518C>T p.F506= | Silent (SNP) | VAF 326/760 reads (43%) | called by muse, varscan2
- EPS8L3 | c.54G>A p.Q18= | Silent (SNP) | VAF 156/433 reads (36%) | called by muse, mutect2, varscan2
- FOXR2 | c.738C>T p.F246= | Silent (SNP) | VAF 699/1119 reads (62%) | called by muse, mutect2, varscan2
- FRMPD3 | c.4845C>T p.A1615= | Silent (SNP) | VAF 256/1294 reads (20%) | called by muse, mutect2, varscan2
- GRIN2A | c.789G>A p.G263= | Silent (SNP) | VAF 293/461 reads (64%) | called by muse, mutect2, varscan2
- HMGCR | c.33C>T p.L11= | Silent (SNP) | VAF 211/211 reads (100%) | called by muse, mutect2, varscan2
- ITGA5 | c.372A>C p.S124= | Silent (SNP) | VAF 100/213 reads (47%) | called by muse, mutect2, varscan2
- ITGA9 | c.1911C>T p.L637= | Silent (SNP) | VAF 269/269 reads (100%) | called by muse, mutect2, varscan2
- JAG1 | c.3291G>A p.R1097= | Silent (SNP) | VAF 502/846 reads (59%) | called by muse, mutect2, varscan2
- KALRN | c.7287G>A p.K2429= (on ENST00000360013 / NM_001024660.4; = p.K732= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 166/241 reads (69%) | called by muse, mutect2, varscan2
- KCNJ1 | c.475C>T p.L159= | Silent (SNP) | VAF 291/438 reads (66%) | catalogued as rs892013110, COSV60661878; called by muse, mutect2, varscan2
- KCNU1 | c.2139G>A p.R713= | Silent (SNP) | VAF 93/415 reads (22%) | called by muse, mutect2, varscan2
- KIAA1755 | c.2724G>A p.Q908= | Silent (SNP) | VAF 425/1134 reads (37%) | catalogued as rs1450329008, COSV54075312; called by muse, mutect2, varscan2
- KRT82 | c.270C>T p.A90= | Silent (SNP) | VAF 165/379 reads (44%) | called by muse, varscan2
- LRFN4 | c.372C>T p.H124= | Silent (SNP) | VAF 430/633 reads (68%) | called by muse, varscan2
- LRP1B | c.1074G>A p.G358= | Silent (SNP) | VAF 254/527 reads (48%) | called by muse, mutect2, varscan2
- MC3R | c.903C>T p.F301= | Silent (SNP) | VAF 300/742 reads (40%) | called by muse, mutect2, varscan2
- MISP | c.246C>T p.L82= | Silent (SNP) | VAF 485/720 reads (67%) | catalogued as COSV53122333; called by muse, mutect2, varscan2
- MPP5 | c.12C>T p.S4= | Silent (SNP) | VAF 52/109 reads (48%) | called by muse, mutect2, varscan2
- MUC16 | c.8217C>T p.T2739= | Silent (SNP) | VAF 103/353 reads (29%) | called by muse, mutect2, varscan2
- MYH3 | c.2655G>A p.K885= | Silent (SNP) | VAF 313/315 reads (99%) | called by muse, mutect2, varscan2
- MYLK | c.156C>T p.F52= | Silent (SNP) | VAF 269/269 reads (100%) | catalogued as rs200095645, COSV60604762; ClinVar: likely benign; called by muse, mutect2, varscan2
- MZF1 | c.1938C>T p.I646= | Silent (SNP) | VAF 240/818 reads (29%) | catalogued as rs575997059, COSV99285405; called by muse, varscan2
- OR5AS1 | c.891G>A p.V297= | Silent (SNP) | VAF 59/178 reads (33%) | catalogued as rs1565026622, COSV57982068; called by muse, mutect2, varscan2
- OR6M1 | c.831G>A p.V277= | Silent (SNP) | VAF 243/360 reads (68%) | catalogued as rs188523790, COSV100484093; called by muse, varscan2
- OR9A4 | c.48C>T p.F16= | Silent (SNP) | VAF 175/484 reads (36%) | catalogued as COSV71885476; called by muse, mutect2, varscan2
- OTOP3 | c.228G>A p.L76= | Silent (SNP) | VAF 541/541 reads (100%) | called by muse, varscan2
- PATL1 | c.735C>T p.L245= | Silent (SNP) | VAF 157/243 reads (65%) | called by muse, mutect2, varscan2
- PODNL1 | c.13C>T p.L5= | Silent (SNP) | VAF 152/483 reads (31%) | catalogued as rs1252923978; called by muse, mutect2, varscan2
- POTEG | c.60C>T p.L20= | Silent (SNP) | VAF 102/640 reads (16%) | catalogued as rs1397268766; called by muse, varscan2
- PPP2R1A | c.1509C>T p.F503= | Silent (SNP) | VAF 131/357 reads (37%) | catalogued as rs1241423356, COSV59042338; called by muse, mutect2, varscan2
- PPP3R2 | c.324C>T p.S108= | Silent (SNP) | VAF 146/508 reads (29%) | catalogued as rs1369225216; called by muse, varscan2
- PRSS57 | c.825C>T p.T275= | Silent (SNP) | VAF 333/525 reads (63%) | catalogued as rs748790336; called by muse, varscan2
- RGPD4 | c.5097G>A p.R1699= | Silent (SNP) | VAF 204/447 reads (46%) | called by muse, mutect2, varscan2
- RXRG | c.1155C>T p.S385= | Silent (SNP) | VAF 177/284 reads (62%) | catalogued as rs751447894; called by muse, mutect2, varscan2
- SCARA5 | c.372G>A p.Q124= | Silent (SNP) | VAF 674/940 reads (72%) | called by muse, varscan2
- SCN10A | c.2547G>A p.E849= | Silent (SNP) | VAF 464/465 reads (100%) | called by muse, mutect2, varscan2
- SHC1 | c.1389C>T p.P463= (on ENST00000368445 / NM_183001.5; = p.P354= on NM_003029.5) | Silent (SNP) | VAF 180/282 reads (64%) | catalogued as rs1304736404; called by muse, varscan2
- SLAMF8 | c.360G>A p.K120= | Silent (SNP) | VAF 221/348 reads (64%) | called by muse, mutect2
- SLC46A2 | c.1401A>C p.S467= | Silent (SNP) | VAF 147/415 reads (35%) | called by muse, mutect2, varscan2
- SLC9A2 | c.528G>A p.G176= | Silent (SNP) | VAF 308/612 reads (50%) | catalogued as COSV52137567; called by muse, varscan2
- STAB2 | c.3687C>T p.F1229= | Silent (SNP) | VAF 96/214 reads (45%) | catalogued as COSV66334152; called by muse, mutect2, varscan2
- TNFRSF10B | c.756T>G p.G252= | Silent (SNP) | VAF 120/546 reads (22%) | called by muse, varscan2
- TSPAN8 | c.198C>T p.I66= | Silent (SNP) | VAF 121/236 reads (51%) | called by muse, mutect2, varscan2
- XAGE5 | c.261G>A p.G87= | Silent (SNP) | VAF 166/464 reads (36%) | called by muse, varscan2
- YIPF3 | c.1038C>T p.T346= | Silent (SNP) | VAF 228/460 reads (50%) | catalogued as COSV58306729; called by muse, varscan2
- ZBTB10 | c.186G>A p.G62= | Silent (SNP) | VAF 208/970 reads (21%) | catalogued as COSV66947923; called by muse, varscan2
- ZFHX4 | c.4272G>A p.A1424= | Silent (SNP) | VAF 150/666 reads (23%) | catalogued as rs199795783; called by muse, mutect2, varscan2
- ZNF182 | c.1566C>T p.A522= | Silent (SNP) | VAF 139/762 reads (18%) | called by muse, mutect2, varscan2
- ANKS6 | c.*791C>T | 3'UTR (SNP) | VAF 134/486 reads (28%) | catalogued as COSV62049051; called by muse, mutect2, varscan2
- ASF1B | c.402+20C>T | Intron (SNP) | VAF 190/646 reads (29%) | catalogued as rs551592911; called by muse, varscan2
- DCHS2 | n.6569G>A | RNA (SNP) | VAF 127/431 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+20575C>T | Intron (SNP) | VAF 97/252 reads (38%) | catalogued as rs137903564; called by muse, mutect2, varscan2
- LEKR1 | c.*671G>A | 3'UTR (SNP) | VAF 258/258 reads (100%) | called by muse, varscan2
- MYC | chr8:127735814 T>G | 5'Flank (SNP) | VAF 243/339 reads (72%) | called by muse, mutect2, varscan2
- RIT2 | c.234+25053G>A | Intron (SNP) | VAF 263/405 reads (65%) | called by muse, mutect2, varscan2
- TTN | c.10361-4350G>A | Intron (SNP) | VAF 160/315 reads (51%) | catalogued as rs1288130040; called by muse, mutect2, varscan2
